Somatic mutation profile of tumor specimen 0DPQQQ from CCDI case PBCEBZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.8 years (1,761 days).
Specimen 0DPQQQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96c5fb3b-39f5-40fc-ab4c-2707319c518b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQQE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f022069-caa3-4969-af8c-fb4420cb166c

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 3'UTR 2, Silent 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB10 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 100/363 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775064026, COSV51998277; called by muse, mutect2, varscan2
- CYP4F8 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 113/177 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57855688; called by muse, mutect2, varscan2
- KCNJ12 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 79/397 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs529503169, COSV59166116; called by muse, mutect2, varscan2
- MAST4 | c.4916C>T p.A1639V (on ENST00000403625 / NM_001164664.2; = p.A1450V on NM_015183.3) | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.012); catalogued as rs1272182044; called by muse, mutect2, varscan2
- OR4C12 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 272/826 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs1236333452; called by muse, mutect2
- TBCD | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.839); catalogued as rs1284143195; called by muse, mutect2, varscan2
- WASHC2C | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs782209581; called by muse, mutect2, varscan2
- ZSCAN1 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); catalogued as rs957357430, COSV56606351; called by muse, mutect2, varscan2
- CBLIF | c.1073+1G>T p.X358_splice | Splice Site (SNP) | VAF 156/262 reads (60%) | called by muse, mutect2, varscan2
- ITPR1 | c.6778C>G p.L2260V (on ENST00000354582; = p.L2205V on NM_002222.7) | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PER2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 98/109 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- SMAD2 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 137/398 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HBA2 | c.267G>A p.A89= | Silent (SNP) | VAF 16/20 reads (80%) | called by mutect2, varscan2
- LRRK1 | c.1818C>A p.T606= | Silent (SNP) | VAF 99/221 reads (45%) | catalogued as COSV99441391; called by mutect2, varscan2
- CLRN1 | c.*1032del | 3'UTR (DEL) | VAF 50/144 reads (35%) | catalogued as rs768607634, COSV55806699; called by mutect2, varscan2
- GH2 | c.-3G>T | 5'UTR (SNP) | VAF 138/469 reads (29%) | called by muse, mutect2, varscan2
- RAB34 | c.*22G>C | 3'UTR (SNP) | VAF 104/333 reads (31%) | called by muse, mutect2, varscan2
